Gene-level copy-number profile of tumor specimen TCGA-61-1736-01B from TCGA case TCGA-61-1736, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 45.5 years (16,613 days).
Specimen TCGA-61-1736-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.f2a87dfd-48e3-4ca8-be68-808d869dbfec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1736-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8ab75fde-ff48-4d94-9bca-7d51a23afd8f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 18,116; copy number 2: 37,268; copy number 3: 4,052; copy number 4: 374.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1736-01B-01D-0663-01): tumor purity 0.81, ploidy 1.85, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:27,851,669–28,008,581, 6 genes (within-gene range 0–1): PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1.
- chr22:27,994,474–28,056,453, 3 genes: AL033538.1, AL033538.2, RN7SL757P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 15,757. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
